Gene-level copy-number profile of tumor specimen ALCH-B20I-TTP1-A from ALCHEMIST case ALCH-B20I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.1 years (28,161 days).
Specimen ALCH-B20I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e2679abe-36e2-4259-87bf-29de11e2f29c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B20I-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/70040a05-1dc2-40ef-bfae-893977355875

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,823; copy number 2: 52,324; copy number 3: 2,181; copy number 4: 62; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–6): IGKV1D-12.
- chr3:52,228,612–52,246,788, 1 gene (within-gene range 0–2): TWF2.
- chr4:188,159,705–188,161,157, 1 gene: LINC02434.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,121,786–90,154,574, 2 genes, copy number 6: IGKV2D-14, IGKV1D-13.
- chr2:90,172,802–90,173,414, 1 gene, copy number 6: IGKV3D-11.
- chr17:2,049,908–2,050,380, 2 genes, copy number 6: MIR132, MIR212.

Autosomal genes at a single copy (total copy number 1): 2,193. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
